ORGANOID case 2 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/668518ae-43b6-4daf-85e8-20f3a512027c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; AJCC pathologic stage: Stage IV.

Biospecimens (2 samples)
- Samples S131, S171 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid.
